Gene-level copy-number profile of tumor specimen TCGA-5U-AB0D-01A from TCGA case TCGA-5U-AB0D, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.6 years (26,167 days).
Specimen TCGA-5U-AB0D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-THYM.8c9c1d79-5c6e-492a-bc5c-ab5233168813.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-5U-AB0D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/54ddbb8f-faad-40a8-a2c7-81f18fc3a2c5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 51; copy number 2: 5,617; copy number 3: 18,765; copy number 4: 24,783; copy number 5: 8,922; copy number 6: 1,293; copy number 7: 37; copy number 8: 322; copy number 9: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-5U-AB0D-01A-11D-A422-01): tumor purity 0.7, ploidy 3.68, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 27 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:57,071,814–58,060,739, 27 genes, copy number 9: AC007114.1, AKAP1, AC007114.2, AC003950.1, AC091181.2, MSI2, AC091181.1, AC015883.1, AC007431.2, AC007431.3, AC007431.1, RN7SL449P, RNU7-134P, CCDC182, AC015845.2, RN7SKP94, MRPS23, CUEDC1, AC015845.1, AC015813.4, VEZF1, AC015813.7, AC015813.2, AC015813.1, SRSF1, AC015813.5, AC015813.8.

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
